Somatic mutation profile of tumor specimen TCGA-DW-7836-01A (aliquot TCGA-DW-7836-01A-11D-2136-08) from TCGA case TCGA-DW-7836, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 55.5 years (20,269 days).
Specimen TCGA-DW-7836-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5302241-4083-466c-abcd-71f57bfdba95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7836-10A (Blood Derived Normal), aliquot TCGA-DW-7836-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30a369bb-eeb8-424e-90ec-2fab0ecd057f

The open-access MAF lists 46 somatic variants for this specimen: 36 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Nonsense Mutation 4, Frame Shift Del 3, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN4 | c.2474T>C p.L825P | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV99399792; called by muse, mutect2, varscan2
- ADAM32 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 11/16 reads (69%) | catalogued as COSV101165254; called by muse, mutect2, varscan2
- ADGRE2 | c.706T>A p.Y236N | Missense Mutation (SNP) | VAF 31/152 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV100215702; called by muse, mutect2, varscan2
- ADGRE5 | c.697T>A p.Y233N (on ENST00000242786 / NM_078481.4; = p.Y140N on NM_001784.5) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99662573; called by mutect2, varscan2
- AHNAK | c.3087T>G p.I1029M | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV99945638; called by muse, mutect2, varscan2
- ARHGEF17 | c.2018C>A p.S673* | Nonsense Mutation (SNP) | VAF 5/58 reads (9%) | catalogued as COSV99734918; called by muse, mutect2
- ARSL | c.790C>T p.Q264* | Nonsense Mutation (SNP) | VAF 37/39 reads (95%) | catalogued as COSV101140404; called by muse, mutect2, varscan2
- CACNA1S | c.4775C>T p.A1592V | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1037769687, COSV100754664; called by muse, mutect2, varscan2
- DUS3L | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100287890; called by muse, mutect2, varscan2
- EFS | c.44A>T p.D15V | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99391387; called by muse, mutect2, varscan2
- FGF12 | c.308A>G p.Y103C (on ENST00000454309 / NM_021032.5; = p.Y41C on NM_004113.6) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.743); catalogued as rs1229502475, COSV99279037; called by muse, mutect2, varscan2
- FOXN1 | c.1902del p.S635Lfs*41 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as COSV56884648; called by mutect2, pindel, varscan2
- GAB4 | c.1526C>G p.P509R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as COSV101271883, COSV101272003; called by muse, mutect2, varscan2
- KLB | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.94); PolyPhen benign (0.015); catalogued as rs781587328, COSV57303036, COSV57304910; called by muse, mutect2, varscan2
- KRT3 | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 49/128 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.452); catalogued as COSV100526888; called by muse, mutect2, varscan2
- LRRC59 | c.538A>T p.K180* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | catalogued as COSV56813930, COSV99869373; called by muse, mutect2, varscan2
- LYG2 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100283552; called by muse, mutect2, varscan2
- METTL4 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170473; called by muse, mutect2, varscan2
- MYO1C | c.404C>G p.A135G (on ENST00000648651 / NM_001080779.2; = p.A100G on NM_033375.5) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV100704245; called by muse, varscan2
- NLRP1 | c.2281A>T p.S761C | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99333003; called by muse, mutect2, varscan2
- NPY2R | c.973T>C p.Y325H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100279452; called by muse, mutect2, varscan2
- POLR3E | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100241919; called by muse, mutect2, varscan2
- PPP3CB | c.1148A>G p.D383G | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100646035; called by muse, mutect2, varscan2
- RBM5 | c.160T>G p.Y54D | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100762151; called by muse, mutect2, varscan2
- SEC14L2 | c.493A>C p.K165Q | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100464343; called by muse, mutect2, varscan2
- SLC26A4 | c.1406C>A p.P469H | Missense Mutation (SNP) | VAF 69/110 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV99706547; called by muse, mutect2, varscan2
- SUPT6H | c.1260G>A p.M420I | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.447); catalogued as COSV100112130; called by muse, mutect2, varscan2
- SYNE2 | c.13103C>T p.S4368F | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100646714; called by muse, mutect2, varscan2
- TMEM52B | c.388T>C p.S130P (on ENST00000381923 / NM_001079815.1; = p.S110P on NM_153022.4) | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV53728693; called by muse, mutect2, varscan2
- TNS1 | c.818T>A p.I273N | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99409861, COSV99411292; called by muse, mutect2, varscan2
- TOMM40L | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as COSV100915504; called by muse, mutect2, varscan2
- ZNF395 | c.700dup p.H234Pfs*19 | Frame Shift Ins (INS) | VAF 14/42 reads (33%) | catalogued as rs768191349; called by mutect2, varscan2
- ZNF559 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100416413, COSV100416481; called by muse, mutect2, varscan2
- ZNF559 | c.721T>A p.Y241N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100416414; called by muse, mutect2, varscan2
- ALS2 | c.2344del p.Y782Ifs*28 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- CSMD3 | c.2265_2266delinsC p.S757Afs*96 (on ENST00000297405 / NM_001363185.1; = p.S653Afs*96 on NM_052900.3) | Frame Shift Del (DEL) | VAF 51/141 reads (36%) | called by pindel, varscan2*
- DDX11 | c.729G>A p.V243= | Silent (SNP) | VAF 40/156 reads (26%) | catalogued as COSV99298955; called by muse, varscan2
- DUSP23 | c.366T>A p.I122= | Silent (SNP) | VAF 37/74 reads (50%) | catalogued as COSV100929114; called by muse, mutect2, varscan2
- ERO1B | c.1204T>C p.L402= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV99934447; called by muse, varscan2
- KCNQ5 | c.2109C>T p.Y703= | Silent (SNP) | VAF 75/163 reads (46%) | catalogued as rs746516968, COSV59655344; called by muse, mutect2, varscan2
- LTBP1 | c.732T>A p.P244= | Silent (SNP) | VAF 56/156 reads (36%) | catalogued as COSV100616409; called by muse, mutect2, varscan2
- MRC1 | c.1240C>T p.L414= | Silent (SNP) | VAF 88/236 reads (37%) | called by muse, mutect2
- NUDC | c.747T>C p.N249= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV100264375, COSV57672054; called by muse, mutect2, varscan2
- OR2AK2 | c.918A>G p.G306= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV100823141; called by muse, mutect2, varscan2
- SNTB2 | c.981G>A p.K327= | Silent (SNP) | VAF 42/68 reads (62%) | catalogued as rs1015423341, COSV100292995, COSV60350969; called by muse, mutect2, varscan2
- MIR524 | n.15C>T | RNA (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2, varscan2
